CCDI case PBCFID — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fa1d6a73-2edd-4550-b18a-8dc7bef17192

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,153 days).

Biospecimens (2 samples)
- Sample 0DQOF0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQOFA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
